Surgical pathology report (de-identified scan), TCGA case TCGA-32-1986, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1986-01A (Primary Tumor).

Tumor ID#

Date of Surgery:

Microscopic Description:

Sections demonstrate recurrent glioblastoma characterized by a hypercellular proliferation of cells which resemble astrocytes. The tumor cells demonstrate marked atypical features, including hyperchromatic and often bizarre nuclei. Many of the tumor cells exhibit ample eosinophilic cytoplasm consistent with gemistocytic differentiation. Mitotic figures, including granular mitoses are readily identified. Numerous thrombosed blood vessels are present. Necrosis, including pseudopalisading necrosis, is also identified. These histologic features are consistent with recurrent glioblastoma.

Diagnosis:

Right temporal lobe, Glioblastoma (WHO grade IV) Recurrent

Diagnosis Discrepancy	Recurrent / Pathology	

Source: NCI Genomic Data Commons file 8ee9f123-c70c-4c44-8415-2d6766d309b4 (TCGA-32-1986.383EFC6E-DABF-409C-A6DB-6A80A5118249.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).